Gene-level copy-number profile of tumor specimen TCGA-DA-A95Y-06A from TCGA case TCGA-DA-A95Y, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.4 years (25,354 days).
Specimen TCGA-DA-A95Y-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.17d5da8b-6cd1-4a83-84bf-cfc67c2fdac6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DA-A95Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bceec82b-0c1e-4e8f-9efb-cdc029db2e11

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 13; copy number 2: 8,118; copy number 3: 9,399; copy number 4: 32,732; copy number 5: 3,813; copy number 6: 3,102; copy number 7: 788; copy number 8: 799; copy number 9: 662; copy number 10: 13; copy number 11: 32; copy number 13: 160; copy number 15: 8; copy number 16: 172.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DA-A95Y-06A-11D-A371-01): tumor purity 0.75, ploidy 3.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,047 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:232,983,435–236,764,631, 96 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr1:236,819,634–236,820,518, 1 gene, copy number 9: RPSAP21.
- chr1:240,775,514–241,357,230, 1 gene, copy number 9 (within-gene range 7–9): RGS7.
- chr1:241,132,272–248,919,946, 219 genes, copy number 9 (broad region; genes not listed).
- chr9:30,831,878–33,410,553, 43 genes, copy number 9: RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4, BAG1, CHMP5, NFX1, Y_RNA, AQP7, AL356218.2.
- chr11:68,612,899–81,040,236, 345 genes, copy number 10–16 (broad region; genes not listed).
- chr11:94,021,354–96,985,810, 56 genes, copy number 9–11 (within-gene range 7–11): HEPHL1, PHBP16, PANX1, AP002784.1, ARPC3P3, IZUMO1R, GPR83, MRE11, MIR548L, AP000786.1, ANKRD49, C11orf97, FUT4, PIWIL4, AP000943.2, AP000943.3, AP000943.1, LINC02700, AMOTL1, AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2, AP000787.1, SESN3, AP000787.3, AP001790.1, AP000820.2, AP000820.1, AP001877.1, FAM76B, CEP57, MTMR2, RNA5SP345, AP000870.1, MAML2, AP000779.1, MIR1260B, CCDC82, JRKL, JRKL-AS1, RNA5SP346, LINC02737, AP003066.1, AP003066.2.
- chr12:56,588,518–57,896,482, 80 genes, copy number 9–15 (within-gene range 6–15) (broad region; genes not listed).
- chr13:63,811,014–64,076,044, 6 genes, copy number 9: PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1.
- chr20:31,637,912–37,445,534, 200 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
